Somatic mutation profile of tumor specimen C3L-02115-02 (aliquot CPT0109110012) from CPTAC case C3L-02115, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 80.0 years (29,237 days).
Specimen C3L-02115-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7681461-771a-4492-a673-3c9f56fe5e5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02115-31 (Blood Derived Normal), aliquot CPT0109140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3af65924-2fc3-4d0d-b68b-97244008ad86

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 5, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 30/296 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PCDHA5 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 23/552 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV100972129; called by muse, mutect2
- SMAD4 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM144214, COSV61684333; called by muse, mutect2
- VANGL2 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV63604324; called by muse, mutect2
- PODNL1 | c.717C>G p.Y239* | Nonsense Mutation (SNP) | VAF 9/268 reads (3%) | called by muse, mutect2
- TRIM49B | c.291G>T p.R97S | Missense Mutation (SNP) | VAF 15/330 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); called by muse, mutect2
- DLGAP3 | c.2361C>T p.R787= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as rs755715413; called by muse, mutect2
- DSCAM | c.2937G>A p.A979= | Silent (SNP) | VAF 13/298 reads (4%) | catalogued as rs1031920480, COSV68027706; called by muse, mutect2
- GAS2L2 | c.717C>T p.N239= | Silent (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- GUCY2D | c.321G>A p.T107= | Silent (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- IGHV4-28 | c.123C>T p.C41= | Silent (SNP) | VAF 12/336 reads (4%) | catalogued as rs376044890; called by muse, mutect2
- STMND1 | c.82-4095G>A | Intron (SNP) | VAF 5/92 reads (5%) | catalogued as rs1437975802; called by muse, mutect2
